FM case AD4177 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified urinary organs.
https://portal.gdc.cancer.gov/cases/dbf6c627-3d4d-4885-a07c-50a712f5a3dc

Female, 62.9 years: diagnosis not reported by GDC of the urinary system; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
